Somatic mutation profile of tumor specimen 0DPBGB from CCDI case PBBZXE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,152 days).
Specimen 0DPBGB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd9a3889-fa2a-4631-9a1c-535cd8fcbedc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBF8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d442ca2a-b686-49ed-9477-b59c9bec2a19

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHIP | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 39/374 reads (10%) | catalogued as COSV51508010; called by muse, mutect2
- SRRM2 | c.5964G>A p.P1988= | Silent (SNP) | VAF 31/484 reads (6%) | catalogued as rs776779115, COSV99241776; called by muse, mutect2
